Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VB, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VB-01A (Primary Tumor).

[page 1 of 3]
IHPAA Discrepancy		✓

& Neck
And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:
Papillary thyroid carcinoma, PTC

Specimens Submitted:

- 1: Biopsy of trachea (fs)
- 2: Left paratracheal tissue (fs)
- 3: Total thyroidectomy

DIAGNOSIS:

1. Trachea; biopsy (fs):
- Benign respiratory mucosa.
2. Paratracheal Left ; biopsy(fs):
- Metastatic papillary carcinoma to lymph node, the node is 0.5cm and the metastatic focus is 0.25cm in size
- No extranodal extension seen

Note : the carcinoma was not present on the original frozen section slide

3. Total thyroidectomy:

Part # 3

Tumor Type:

Papillary carcinoma, tall cell variant $\geq 50\%$ Tall cell variant per TSS /hr

Mitotic Activity:

Not identified

ICD-O-3

Tumor Necrosis:

Not identified

Carcinoma, papillary, tall cell
8344/3

Tumor Location:

Left lobe

Site: thyroid, NOS

Tumor Size:

Greatest diameter is 5.2 cm.

C73.9 5-2-12
20

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades: peri-thyroid fibroadipose tissue

Surgical Margins:

Free of tumor

[page 2 of 3]
Tumor Multicentricity:

Separate foci of papillary carcinoma, follicular and microcarcinoma variants in right lobe. The follicular variant is encapsulated non-invasive (3.7 cm)

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "biopsy of trachea" and consists of two tiny fragments of tissue each measuring less than 0.1 cm in greatest dimension. The entire specimen is submitted for frozen section. The specimen may not survive processing.

Summary of sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section consultation, labeled "left paratracheal tissue" and consists of a 1.1 x 1.0 x 0.3 cm piece of soft tissue. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

3). The specimen is received in formalin, labeled "total thyroidectomy, suture marks right lobe of thyroid" and consists of a 52 g thyroid with a suture marking the right pole. The right lobe measures 6.7 x 3.4 x 1.7 cm, the left lobe measures 5.7 x 5.2 x 2.5 cm and the isthmus measures 3 x 2.6 x 1 cm. The external surface is covered by a thin fibrous capsule with an anteriorly attached, 5.5 x 3.5 x 2 cm portion of muscular tissue on the isthmus and left lobe. The specimen is previously inked anterior blue and posterior black. Sectioning reveals three ovoid, tan-white to pink-tan, rubbery, focally tan-yellow, gelatinous, unencapsulated nodules in the mid to lower poles of the right lobe, the two smaller measuring 0.6 x 0.4 x 0.4 cm and the largest measuring 3.7 x 2.4 x 2.4 cm. The largest nodule abuts both the anterior and posterior capsular aspects. In the left lobe is a 5.2 x 2.4 x 2.3 cm tan-brown, friable, finely focally encapsulated nodule which abuts the anterior and posterior capsular aspects. The remaining thyroid parenchyma is red tan and meaty. Representative sections are submitted.

Summary of sections:

RLN - right lobe nodules

RL - right lobe

LLN - left lobe nodule

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Biopsy of trachea (fs)

Block	Sect. Site	PCs
-------	------------	-----

[page 3 of 3]
1 FSC 1

Part 2: Left paratracheal tissue (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 3: Total thyroidectomy

Block	Sect. Site	PCs
2	IS	2
1	LL	2
15	LLN	15
3	RL	3
8	RLN	8

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Biopsy of trachea (fs): Predominantly calcified tissue with rare epithelial cells. Defer. 4
Permanent Diagnosis: same
2. Frozen Section Diagnosis: Left paratracheal tissue (fs): Benign lymph node. p)
Permanent Diagnosis: see final

Source: NCI Genomic Data Commons file 589341c3-0245-450f-aa10-9c91dd77ca77 (TCGA-DJ-A3VB.CAE279C4-3563-419D-9BC7-9FB54A3C58FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).